Surgical pathology report (de-identified scan), TCGA case TCGA-W5-AA31, project TCGA-CHOL (Cholangiocarcinoma), tissue source site Mayo Clinic Rochester, specimen TCGA-W5-AA31-01A (Primary Tumor).

Male

Surgery Date:

DIAGNOSIS:

Liver, extended right hepatectomy: Poorly differentiated intrahepatic cholangiocarcinoma, with extensive necrosis, is identified forming a 7.6 x 6.3 x 4.5 cm tumor that comes to within less than 0.1 cm of the inked parenchymal resection margin.

Angiolymphatic space invasion is not identified. Multiple (4) perihilar lymph nodes are identified and are negative for metastatic carcinoma. The background hepatic parenchyma shows only minimal changes. See comment

ICD-O-3

Cholangiocarcinoma NOS 8160/3

Site: Intrahepatic bile duct C22.1

W 3/8/14

Source: NCI Genomic Data Commons file 8cb7a72b-4b27-4bf3-b36e-cb040d5758b5 (TCGA-W5-AA31.A3B869CE-5B61-4F3E-930E-BC6CB37DD4F0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).